Gene-level copy-number profile of tumor specimen TCGA-AN-A0XR-01A from TCGA case TCGA-AN-A0XR, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 55.8 years (20,381 days).
Specimen TCGA-AN-A0XR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.73792381-9fcb-4a9f-b192-9eb30f94a4fa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0XR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0e2f56f1-0284-412b-86a1-e33d4cac081e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,514; copy number 2: 49,058; copy number 3: 5,810; copy number 4: 153; copy number 5: 29; copy number 6: 201; copy number 7: 5; copy number 9: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0XR-01A-11D-A107-01): tumor purity 0.85, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 272 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:57,255,851–57,684,689, 1 gene, copy number 6 (within-gene range 3–6): MSI2.
- chr17:57,448,218–62,841,645, 184 genes, copy number 6–9 (broad region; genes not listed).
- chr17:66,197,693–66,894,751, 12 genes, copy number 6 (within-gene range 3–6): PSMD7P1, APOH, RNA5SP444, AC009452.1, PRKCA, RN7SL735P, PRKCA-AS1, RNU6-928P, RNA5SP445, AC006947.1, MIR634, CACNG5.
- chr17:67,377,281–68,524,949, 40 genes, copy number 6 (within-gene range 2–6): PITPNC1, Y_RNA, RN7SL756P, MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1, AC079331.3, NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635.
- chr17:69,078,702–71,298,218, 29 genes, copy number 5: ABCA6, SEC24AP1, MIR4524B, MIR4524A, ABCA10, PRO1804, AC005495.1, ABCA5, SNRPGP4, AC115085.1, MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P.
- chr17:72,067,099–72,237,203, 1 gene, copy number 6 (within-gene range 2–6): SOX9-AS1.
- chr20:4,686,350–4,761,696, 5 genes, copy number 7: PRNP, PRND, PRNT, IDI1P3, AL133396.1.

Autosomal genes at a single copy (total copy number 1): 4,514. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
